Gene-level copy-number profile of tumor specimen TCGA-3A-A9IN-01A from TCGA case TCGA-3A-A9IN, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 62.4 years (22,799 days).
Specimen TCGA-3A-A9IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.302ac5a6-352c-4633-9940-9aa6d9704b98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9IN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf8249cb-14f7-40cb-8cf5-fcab4f26333c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 4,467; copy number 2: 29,317; copy number 3: 6,893; copy number 4: 18,758; copy number 5: 248; copy number 6: 46; copy number 7: 9; copy number 8: 1; copy number 9: 8; copy number 10: 1; copy number 12: 1; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9IN-01A-11D-A396-01): tumor purity 0.69, ploidy 1.41, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,331,664, 40 genes (within-gene range 0–1): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1.
- chr3:153,357,107–153,377,562, 2 genes: AC078788.1, AC078788.2.
- chr6:168,716,606–168,723,495, 1 gene: AL136099.1.
- chr6:169,157,162–169,182,841, 2 genes: LINC01615, LINC02544.
- chr9:16,775,573–16,775,845, 1 gene: LSM1P1.
- chr10:36,432,882–36,995,585, 9 genes: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2.
- chr21:23,352,929–23,968,747, 9 genes: D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 209 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,167,159–10,295,579, 9 genes, copy number 6–9: AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:13,977,166–14,242,813, 4 genes, copy number 6–7 (within-gene range 4–7): AC095052.1, LINC01085, AC073848.1, AC092546.1.
- chr4:77,157,207–77,433,388, 4 genes, copy number 6–14 (within-gene range 4–14): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr4:142,023,160–144,870,953, 29 genes, copy number 5 (within-gene range 4–5): INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA, AC098588.3.
- chr4:144,505,900–144,509,001, 1 gene, copy number 5: AC106871.1.
- chr5:37,811,589–37,953,827, 1 gene, copy number 7 (within-gene range 4–7): GDNF-AS1.
- chr5:37,899,363–37,966,964, 4 genes, copy number 7: LINC02117, AC008869.1, LINC02110, AC034226.1.
- chr5:66,298,394–68,565,515, 30 genes, copy number 5: AC092353.1, AC092353.2, LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1, AC008459.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2, AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2, AC010280.1, AC010280.3.
- chr5:106,815,197–107,810,924, 7 genes, copy number 5 (within-gene range 4–5): LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122.
- chr7:3,083,252–3,302,452, 4 genes, copy number 5: AC024028.1, AC073316.1, AC073316.2, SDK1-AS1.
- chr7:3,337,889–3,338,601, 1 gene, copy number 5: AC092427.1.
- chr8:37,067,441–37,095,390, 2 genes, copy number 5: AC092818.1, SMARCE1P4.
- chr8:139,508,701–139,508,971, 1 gene, copy number 5: AC090093.1.
- chr12:13,044,381–13,982,002, 12 genes, copy number 6 (within-gene range 3–6): FAM234B, GSG1, EMP1, AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr12:28,978,584–28,978,685, 1 gene, copy number 6: AC024255.1.
- chr12:114,104,542–114,105,931, 1 gene, copy number 12: GLULP5.
- chr12:115,263,170–115,886,137, 13 genes, copy number 6: AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3.
- chr17:32,927,910–34,859,046, 39 genes, copy number 5 (within-gene range 3–5): TMEM98, SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr18:45,212,995–45,683,688, 4 genes, copy number 6–7 (within-gene range 4–9): SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3.
- chr19:8,848,844–8,981,342, 1 gene, copy number 10 (within-gene range 3–10): MUC16.
- chr20:39,213,777–43,189,970, 41 genes, copy number 5 (within-gene range 4–5): LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100.

Autosomal genes at a single copy (total copy number 1): 4,466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
